Somatic mutation profile of tumor specimen BA3335D (aliquot aq-BA3335D) from BEATAML1.0 case 2602, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.1 years (20,491 days).
Specimen BA3335D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c306cd7c-114c-4a6b-9c50-fb0c3816fb35.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3437D (Solid Tissue Normal), aliquot aq-BA3437D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a74bc2e2-25a2-4e34-a4df-4e9dbc608aae

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHD6 | c.7900A>C p.M2634L | Missense Mutation (SNP) | VAF 119/313 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.074); catalogued as rs769235551, COSV64688043; called by muse, mutect2, varscan2
- DMRT3 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1435006970; called by muse, mutect2, varscan2
- GATA2 | c.1062delinsTTTT p.T354_T355insF | In Frame Ins (INS) | VAF 76/205 reads (37%) | called by pindel, varscan2*
- KIF21B | c.1911C>T p.A637= | Silent (SNP) | VAF 33/94 reads (35%) | catalogued as rs765071917, COSV100143360; called by muse, mutect2, varscan2
